Gene-level copy-number profile of tumor specimen TCGA-56-7822-01A from TCGA case TCGA-56-7822, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.0 years (27,755 days).
Specimen TCGA-56-7822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d10f97b0-dbca-42a1-be4f-46a57fe91d12.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-7822-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c70306ac-e85f-458c-bf0c-0452888b4558

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 2: 8,976; copy number 3: 20,264; copy number 4: 18,134; copy number 5: 5,816; copy number 6: 1,251; copy number 7: 4,353; copy number 9: 970; copy number 11: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-7822-01A-11D-2121-01): tumor purity 0.31, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,442,380, 2 genes: RPS26P3, RN7SL5P.
- chr9:15,524,576–17,797,124, 22 genes: AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,347 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–9 (broad region; genes not listed).
- chr9:129,712,896–130,501,274, 19 genes, copy number 7: PRRX2-AS1, PTGES, UBE2V1P4, TOR1B, TOR1A, C9orf78, USP20, MIR6855, AL158207.1, FNBP1, AL158207.2, AL136141.1, GPR107, Y_RNA, GPRACR, NCS1, HMCN2, RN7SL665P, ASS1.
- chr12:66,767–990,053, 24 genes, copy number 11 (within-gene range 3–11): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr13:64,958,097–114,337,626, 592 genes, copy number 7 (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
